Gene-level copy-number profile of tumor specimen HCM-BROD-0209-C71-02A from HCMI case HCM-BROD-0209-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 41.8 years (15,280 days).
Specimen HCM-BROD-0209-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a383555b-7f23-48d3-be75-21a13f5872c8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0209-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/c828ab1c-d7ea-4f83-9ba1-8394c0422777

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,952; copy number 2: 40,059; copy number 3: 14,253; copy number 4: 2,594; copy number 5: 21; copy number 7: 3; copy number 31: 9; copy number 34: 7.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–2): NUTM2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 40 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–71,585, 3 genes, copy number 7: OR4G4P, OR4G11P, OR4F5.
- chr7:30,752,137–30,993,254, 6 genes, copy number 5 (within-gene range 4–5): INMT-MINDY4, MINDY4, AC004691.1, AC004691.2, AQP1, GHRHR.
- chr7:54,621,025–55,211,628, 7 genes, copy number 34: RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr17:50,508,384–50,692,253, 9 genes, copy number 31: MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3.
- chr19:18,442,663–18,522,116, 1 gene, copy number 5 (within-gene range 3–5): ELL.
- chr19:18,531,613–18,791,305, 14 genes, copy number 5: AC005387.1, FKBP8, AC005387.2, KXD1, AC005253.1, AC005253.2, UBA52, CRLF1, REX1BD, TMEM59L, RN7SL155P, KLHL26, CRTC1, COMP.

Autosomal genes at a single copy (total copy number 1): 1,440. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
